Somatic mutation profile of tumor specimen TCGA-ER-A19J-06A (aliquot TCGA-ER-A19J-06A-11D-A196-08) from TCGA case TCGA-ER-A19J, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.2 years (19,801 days).
Specimen TCGA-ER-A19J-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36b0ce32-a815-48fb-aa05-e9d5783cfad9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19J-10A (Blood Derived Normal), aliquot TCGA-ER-A19J-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e28801c-1347-45f5-8a86-3693d34d9068

The open-access MAF lists 254 somatic variants for this specimen: 165 protein-altering or splice-affecting, 85 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 85, Nonsense Mutation 9, Splice Site 5, Intron 3, Splice Region 3, Frame Shift Ins 3, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2, varscan2
- SYT13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs868559206, COSV50072436, COSV50073637; called by muse, mutect2
- ABCC9 | c.3315+1G>T p.X1105_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | catalogued as COSV53975659, COSV99686267; called by muse, varscan2
- AC011479.1 | c.186C>T p.F62= | Splice Region (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56648157; called by muse, mutect2
- ADAMTS18 | c.2789C>T p.S930F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs1249046298, COSV51398246; called by muse, mutect2, varscan2
- ADAMTSL4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs150503018, COSV55001451, COSV99647395; called by muse, mutect2, varscan2
- ADCY9 | c.2962C>T p.L988F | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53577066; called by muse, mutect2, varscan2
- AGO3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs752288503; called by muse, mutect2, varscan2
- AK7 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50873706; called by muse, mutect2, varscan2
- AMIGO2 | c.1403T>C p.F468S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56974585; called by muse, mutect2, varscan2
- AP5M1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55105693; called by muse, mutect2, varscan2
- ARHGAP28 | c.1408C>T p.L470F (on ENST00000383472 / NM_001366230.1; = p.L311F on NM_001010000.3) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233278869, COSV51640076; called by muse, mutect2, varscan2
- ARL3 | c.161A>G p.K54R | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV53299929; called by muse, mutect2, varscan2
- BCAS1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 87/135 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV65087170; called by muse, mutect2, varscan2
- BRWD3 | c.3412T>G p.W1138G | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64749598; called by muse, mutect2, varscan2
- CA10 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53355537; called by muse, mutect2, varscan2
- CAMSAP2 | c.3764G>A p.R1255H (on ENST00000236925 / NM_001297707.2; = p.R1244H on NM_203459.3) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763798200, COSV52672620; called by muse, mutect2, varscan2
- CCDC74B | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV60102618; called by muse, mutect2, varscan2
- CD163L1 | c.2322G>A p.W774* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as rs763605724, COSV58018370; called by muse, mutect2, varscan2
- CD2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV65643581; called by muse, mutect2, varscan2
- CDH18 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56903848; called by muse, mutect2, varscan2
- CEMIP | c.2165G>A p.G722E | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54994859; called by muse, mutect2, varscan2
- CGNL1 | c.3160C>T p.H1054Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV55570010; called by muse, mutect2, varscan2
- CLSTN1 | c.1978G>A p.V660I (on ENST00000377298 / NM_001009566.3; = p.V650I on NM_014944.4) | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs560870976, COSV63647845; called by muse, mutect2, varscan2
- CNTNAP4 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs776797989, COSV56686481; called by muse, mutect2, varscan2
- COL3A1 | c.3077G>A p.G1026E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58590774; called by muse, mutect2, varscan2
- COL4A6 | c.4033C>T p.P1345S | Missense Mutation (SNP) | VAF 80/85 reads (94%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV57869439; called by muse, mutect2, varscan2
- COL5A2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as COSV66410857; called by muse, mutect2, varscan2
- CSF2RA | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 107/190 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV62625025; called by muse, mutect2, varscan2
- CSMD3 | c.10637A>G p.K3546R (on ENST00000297405 / NM_001363185.1; = p.K3377R on NM_052900.3) | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV52214433; called by muse, mutect2, varscan2
- CSMD3 | c.3896G>A p.G1299E (on ENST00000297405 / NM_001363185.1; = p.G1195E on NM_052900.3) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52214451; called by muse, mutect2, varscan2
- CSRNP3 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100085882, COSV58780063; called by muse, mutect2, varscan2
- CTNND2 | c.2771G>A p.R924K | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV58898136; called by muse, mutect2, varscan2
- DHRS2 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51632530; called by muse, mutect2, varscan2
- DHRS7C | c.444G>A p.M148I (on ENST00000330255 / NM_001220493.2; = p.M147I on NM_001105571.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57651348; called by muse, mutect2, varscan2
- DNAH11 | c.10812T>A p.N3604K | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60961808; called by muse, mutect2, varscan2
- DNAH5 | c.12589G>A p.E4197K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561102835, COSV54233190; called by muse, mutect2, varscan2
- DNAH5 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749610202, COSV54203222; called by muse, mutect2, varscan2
- DNAH8 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV59456036; called by muse, mutect2, varscan2
- DRC1 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.294); catalogued as COSV55506603; called by muse, mutect2, varscan2
- DRD2 | c.124A>C p.T42P | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV60759222; called by muse, mutect2, varscan2
- DROSHA | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs376262500, COSV60777865; called by muse, mutect2, varscan2
- DSPP | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.083); catalogued as COSV56809939, COSV56811814; called by muse, mutect2, varscan2
- DUOX2 | c.2561G>A p.G854D | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296928111, COSV66532742; called by muse, mutect2, varscan2
- EIF1AX | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV63309326; called by muse, mutect2, varscan2
- ELFN2 | c.2297C>T p.T766M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs780401854, COSV68743765; called by muse, mutect2, varscan2
- EPS15L1 | c.2168C>T p.P723L | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs865983780, COSV50170185; called by muse, mutect2, varscan2
- EXO1 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1222768794, COSV62218027; called by muse, mutect2, varscan2
- FABP9 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 77/95 reads (81%) | SIFT tolerated (0.53); PolyPhen benign (0.294); catalogued as COSV66911628; called by muse, mutect2, varscan2
- FAM135B | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 84/102 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52717578; called by muse, mutect2, varscan2
- FBXL7 | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV61647920; called by muse, mutect2, varscan2
- FOSB | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV62278814; called by muse, mutect2, varscan2
- FRMPD4 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV101043618, COSV66217088; called by muse, mutect2, varscan2
- GHR | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV50116508; called by muse, mutect2, varscan2
- GHR | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1009695851, COSV50116549; called by muse, mutect2, varscan2
- GP9 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV56624332; called by muse, mutect2, varscan2
- GPR143 | c.767+1G>C p.X256_splice | Splice Site (SNP) | VAF 17/20 reads (85%) | catalogued as COSV66632681; called by muse, varscan2
- GPR158 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 35/43 reads (81%) | catalogued as rs1395856560, COSV66273233, COSV66281153; called by muse, mutect2, varscan2
- GRIA2 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52382223; called by muse, mutect2, varscan2
- GRID2 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1229928761, COSV56220795; called by muse, mutect2, varscan2
- GSTA1 | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV58015769; called by muse, mutect2, varscan2
- HGD | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs541367417, COSV52199052; called by muse, mutect2, varscan2
- HPS6 | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 74/90 reads (82%) | catalogued as COSV54625930; called by muse, mutect2, varscan2
- IGKV1D-16 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs375652808; called by muse, mutect2, varscan2
- INSL4 | c.375T>G p.C125W | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53329167; called by muse, mutect2, varscan2
- ITGA4 | c.241T>G p.S81A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.676); catalogued as COSV52001098; called by muse, mutect2, varscan2
- KCNH3 | c.2982G>A p.W994* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV57791385; called by muse, mutect2, varscan2
- KCNH5 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV59751934; called by muse, mutect2, varscan2
- KIF4B | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1481965337, COSV70527979; called by muse, mutect2, varscan2
- KLHDC7A | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs778130409, COSV68770114; called by muse, mutect2, varscan2
- KLHL26 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV56317793; called by muse, mutect2, varscan2
- KRT34 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67450030; called by muse, mutect2, varscan2
- LILRA4 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV52492818; called by muse, mutect2, varscan2
- LRRC14B | c.1316A>C p.D439A | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV57257266; called by muse, mutect2, varscan2
- LUM | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.294); catalogued as COSV57127837; called by muse, mutect2, varscan2
- MACC1 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60543919; called by muse, mutect2, varscan2
- MAN2B2 | c.2054C>T p.T685I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV53453911; called by muse, mutect2, varscan2
- MAP1A | c.6513_6515del p.S2172del | In Frame Del (DEL) | VAF 39/66 reads (59%) | catalogued as rs745774409; called by pindel, varscan2
- ME3 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144643070, COSV62772659; called by muse, mutect2, varscan2
- MECOM | c.2186G>A p.G729E (on ENST00000468789 / NM_001105078.4; = p.G917E on NM_004991.4) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV52959553; called by muse, mutect2, varscan2
- MFAP3L | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs1356456863; called by muse, mutect2
- MPP7 | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 58/78 reads (74%) | catalogued as COSV61734044; called by muse, mutect2, varscan2
- MROH2B | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68185656; called by muse, mutect2, varscan2
- MTNR1A | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56156617; called by muse, mutect2, varscan2
- MUC16 | c.8261G>A p.G2754E | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as COSV67474586; called by muse, mutect2, varscan2
- MUC5B | c.3692G>A p.G1231D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1318838920, COSV71593176; called by muse, mutect2, varscan2
- MYF5 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57355465; called by muse, mutect2, varscan2
- MYH2 | c.1417T>C p.F473L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV55433520; called by muse, mutect2, varscan2
- MYH7 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs397516267, CM1410887, COSV62520552, COSV62523895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV67362620; called by muse, mutect2, varscan2
- MYPN | c.3716C>T p.S1239L | Missense Mutation (SNP) | VAF 78/86 reads (91%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV62735021; called by muse, mutect2, varscan2
- MYT1 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60507647; called by muse, mutect2, varscan2
- NF2 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1351169677, COSV58525333; called by muse, mutect2, varscan2
- NLRP3 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60219626; called by muse, mutect2, varscan2
- NLRP3 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV60226495; called by muse, mutect2, varscan2
- NNMT | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs556654096, COSV55474164; called by muse, mutect2, varscan2
- NUP37 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV51838188; called by muse, mutect2, varscan2
- NYNRIN | c.3655T>A p.F1219I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66843176; called by muse, mutect2, varscan2
- OPRK1 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55569122; called by muse, mutect2, varscan2
- OR10T2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV57780856, COSV57781915; called by muse, mutect2, varscan2
- OR2Y1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV57136439; called by muse, varscan2
- OR4A16 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); catalogued as COSV59043699, COSV59045205; called by muse, mutect2, varscan2
- OR4F6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as rs745953823, COSV61026300; called by muse, mutect2, varscan2
- OR8D1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV63442294; called by muse, mutect2, varscan2
- P4HA1 | c.1453T>C p.W485R | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54962484; called by muse, mutect2, varscan2
- PAX7 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.347); catalogued as COSV64750897; called by muse, mutect2, varscan2
- PCDHA9 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); catalogued as COSV65327893; called by muse, mutect2, varscan2
- PCLO | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 62/71 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100430728, COSV61642955; called by muse, mutect2, varscan2
- PCNT | c.6153T>C p.G2051= | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV64029643; called by muse, mutect2, varscan2
- PEX19 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs560911616, COSV54100715; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PKD1L1 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 67/77 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs1186458770, COSV56968468; called by muse, mutect2, varscan2
- PLCB1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 83/123 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV62044272; called by muse, mutect2, varscan2
- PRB3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 93/393 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs71455365, COSV54387881, COSV54391105; called by muse, mutect2, varscan2
- PROKR1 | c.561G>C p.W187C | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58138006; called by muse, mutect2, varscan2
- PWWP2B | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs572013115, COSV59451253; called by muse, mutect2, varscan2
- RGS22 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 48/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62663483; called by muse, mutect2, varscan2
- RGS7 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs866505496, COSV58531455; called by muse, mutect2, varscan2
- RGS7 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100471887, COSV58541016; called by muse, mutect2, varscan2
- RNF112 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV71978780; called by muse, mutect2, varscan2
- RNF141 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56417300; called by muse, mutect2, varscan2
- SALL1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866692687, COSV51753059; called by muse, mutect2, varscan2
- SCN10A | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 89/105 reads (85%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs267599804, COSV71860817; called by muse, mutect2, varscan2
- SF3B2 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59428702; called by muse, mutect2, varscan2
- SIGLECL1 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); catalogued as COSV57063316, COSV57064615; called by muse, mutect2, varscan2
- SLC16A14 | c.260-1G>A p.X87_splice | Splice Site (SNP) | VAF 20/36 reads (56%) | catalogued as COSV54619252; called by muse, mutect2, varscan2
- SLC24A3 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs1466200894, COSV60122617; called by muse, mutect2, varscan2
- SLC25A26 | c.542A>C p.Q181P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV60915420; called by muse, mutect2, varscan2
- SLC44A5 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63758885, COSV63767539; called by muse, mutect2, varscan2
- SLC4A8 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as COSV60654499; called by muse, mutect2, varscan2
- SLCO6A1 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs766883048, COSV65811522; called by muse, mutect2, varscan2
- SPAG17 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377326727; called by muse, mutect2, varscan2
- SPAG17 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV60461320; called by muse, mutect2, varscan2
- SPATA6 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV64056690, COSV64057445; called by muse, mutect2, varscan2
- SV2C | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59222365; called by muse, mutect2, varscan2
- SVEP1 | c.2551A>G p.K851E | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV57039249; called by muse, mutect2, varscan2
- SYNE3 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62080268; called by muse, mutect2, varscan2
- SYT1 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV54054235; called by muse, mutect2, varscan2
- SYT17 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62546776; called by muse, mutect2, varscan2
- TAOK1 | c.1814G>C p.R605P | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55593706; called by muse, mutect2, varscan2
- TAS2R7 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV53689241; called by muse, mutect2, varscan2
- TBX19 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as rs1385415989, COSV63197757; called by muse, mutect2, varscan2
- TECTA | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs867836820, COSV50691680, COSV50779839; called by muse, mutect2, varscan2
- THOC2 | c.3965C>T p.P1322L | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs1458661447, COSV55548790; called by muse, mutect2, varscan2
- TNFRSF8 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.657); catalogued as rs748922700, COSV55797494; called by muse, mutect2, varscan2
- TRIM51 | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55265852; called by muse, mutect2, varscan2
- TTF1 | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.158); catalogued as rs1470909958, COSV57501976; called by muse, mutect2, varscan2
- TTN | c.22008G>A p.W7336* (on ENST00000591111; = p.W6409* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV60140445; called by muse, mutect2, varscan2
- TTN | c.1248G>A p.V416= | Splice Region (SNP) | VAF 19/60 reads (32%) | catalogued as COSV60140467; called by muse, mutect2, varscan2
- TTN | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | PolyPhen benign (0.039); catalogued as COSV60140532; called by muse, mutect2, varscan2
- UBE2O | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60064523; called by muse, mutect2, varscan2
- USP9Y | c.7317T>G p.S2439R | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV59099701; called by muse, mutect2, varscan2
- VIT | c.1859-1G>A p.X620_splice (on ENST00000389975 / NM_001177969.1; = p.X635_splice on NM_053276.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/24 reads (46%) | catalogued as COSV64895407, COSV64897226; called by muse, mutect2, varscan2
- VPS13B | c.5984-1G>A p.X1995_splice | Splice Site (SNP) | VAF 86/109 reads (79%) | catalogued as COSV62146190; called by muse, mutect2, varscan2
- WNT8A | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV64231333; called by muse, mutect2, varscan2
- ZFPM2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765404652, COSV65873778; called by muse, mutect2, varscan2
- ZNF135 | c.1393C>T p.P465S (on ENST00000313434 / NM_001289401.2; = p.P477S on NM_003436.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746807301, COSV57883161; called by muse, mutect2, varscan2
- ZNF573 | c.1810C>T p.H604Y (on ENST00000536220 / NM_001172692.1; = p.H546Y on NM_152360.3) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs754219425, COSV59823653; called by muse, mutect2, varscan2
- ZNF683 | c.1382C>T p.P461L (on ENST00000403843; = p.P441L on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV62873615; called by muse, mutect2, varscan2
- DUSP6 | c.610_611insA p.P204Hfs*45 | Frame Shift Ins (INS) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- PTEN | c.491dup p.V166Sfs*14 | Frame Shift Ins (INS) | VAF 21/38 reads (55%) | called by mutect2, pindel, varscan2
- SRP54 | c.1382_1384del p.Q461_M462delinsL | In Frame Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- TFIP11 | c.1296_1297insT p.K433* | Frame Shift Ins (INS) | VAF 25/73 reads (34%) | called by mutect2, pindel*, varscan2
- ABCA12 | c.7293C>T p.I2431= (on ENST00000272895 / NM_173076.3; = p.I2113= on NM_015657.3) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV55963419; called by muse, mutect2, varscan2
- AC126283.2 | c.123C>T p.L41= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1483911800, COSV67098987; called by muse, mutect2, varscan2
- ACSS3 | c.1611C>T p.T537= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV54093658; called by muse, mutect2, varscan2
- AHNAK2 | c.11583G>A p.T3861= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as rs1340690805; called by muse, mutect2, varscan2
- ASH1L | c.3909C>T p.I1303= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV64209360; called by muse, mutect2, varscan2
- ATP13A1 | c.1341C>T p.F447= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV52287237; called by muse, mutect2, varscan2
- BAG6 | c.2013C>G p.P671= (on ENST00000676571; = p.P624= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 126/508 reads (25%) | catalogued as COSV52991856; called by muse, mutect2, varscan2
- CACNA1B | c.4185C>T p.F1395= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV53131982; called by muse, mutect2, varscan2
- CADM4 | c.102G>A p.V34= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as COSV55929170; called by muse, mutect2, varscan2
- CALB2 | c.213C>T p.F71= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV56940047; called by muse, mutect2, varscan2
- CBLC | c.678G>A p.K226= | Silent (SNP) | VAF 85/218 reads (39%) | catalogued as COSV54323405; called by muse, mutect2, varscan2
- CCER1 | c.480G>A p.R160= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs753914225, COSV62647280; called by muse, mutect2, varscan2
- CDRT1 | c.966C>T p.H322= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs750487004, COSV55412156; called by muse, mutect2, varscan2
- CMKLR1 | c.351C>T p.F117= (on ENST00000312143 / NM_001142344.2; = p.F115= on NM_004072.3) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV56439131; called by muse, mutect2, varscan2
- COL19A1 | c.1182G>A p.G394= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1174521030, COSV100507159, COSV100507488; called by muse, mutect2, varscan2
- COLEC10 | c.585C>T p.I195= | Silent (SNP) | VAF 104/128 reads (81%) | catalogued as rs745764220, COSV60520576, COSV60522630, COSV60522841; called by muse, mutect2, varscan2
- CPSF6 | c.1545C>T p.D515= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- CSMD1 | c.1758C>T p.F586= (on ENST00000520002; = p.F585= on NM_033225.6) | Silent (SNP) | VAF 7/8 reads (88%) | catalogued as rs752315736, COSV59338608; called by muse, mutect2, varscan2
- DEFB115 | c.213G>A p.K71= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs757642240, COSV68723195; called by muse, mutect2, varscan2
- DNAH10 | c.4962C>T p.I1654= (on ENST00000409039; = p.I1593= on NM_207437.3) | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV68989065, COSV68995673; called by muse, mutect2, varscan2
- DSCAM | c.327G>A p.G109= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV68638075; called by muse, mutect2, varscan2
- DST | c.7077C>T p.A2359= | Silent (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- FAT1 | c.9210C>T p.F3070= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV71672171, COSV71674724; called by muse, mutect2, varscan2
- FBXL7 | c.315C>T p.S105= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV61647916; called by muse, mutect2, varscan2
- FSTL5 | c.1539C>T p.F513= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV60202366; called by muse, mutect2, varscan2
- GABRA6 | c.318G>A p.L106= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV50884051; called by muse, mutect2, varscan2
- GARNL3 | c.1464C>T p.F488= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV59227697, COSV59229111; called by muse, mutect2, varscan2
- GAS7 | c.1383C>T p.V461= (on ENST00000432992 / NM_201433.2; = p.V321= on NM_003644.3) | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV100095966, COSV60438269; called by muse, mutect2, varscan2
- GPHB5 | c.129C>T p.F43= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV58486060; called by muse, mutect2, varscan2
- GRIK4 | c.1374C>T p.I458= | Silent (SNP) | VAF 58/135 reads (43%) | catalogued as COSV70803430; called by muse, mutect2, varscan2
- HAUS7 | c.432C>T p.L144= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs1206394550, COSV57849660; called by muse, mutect2, varscan2
- HOXA6 | c.54G>A p.Q18= | Silent (SNP) | VAF 71/81 reads (88%) | catalogued as COSV56073815; called by muse, mutect2, varscan2
- LACC1 | c.1141C>T p.L381= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV57829310; called by muse, mutect2, varscan2
- LAMB2 | c.2997C>T p.A999= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV59734586; called by muse, mutect2, varscan2
- MAP3K9 | c.1761G>A p.E587= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV67121783; called by muse, mutect2, varscan2
- MUC16 | c.17292T>G p.T5764= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as COSV67474582; called by muse, mutect2, varscan2
- MYO18A | c.613C>T p.L205= | Silent (SNP) | VAF 43/116 reads (37%) | catalogued as COSV62868525; called by muse, mutect2, varscan2
- NLRP13 | c.1080G>A p.L360= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1459802888, COSV61620504, COSV61620781; called by muse, mutect2, varscan2
- NLRP13 | c.156C>T p.F52= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV61620793; called by muse, mutect2, varscan2
- NLRP9 | c.2694C>T p.T898= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs774030442, COSV60464487; called by muse, mutect2, varscan2
- NPAP1 | c.195C>T p.F65= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs1410524056, COSV61504060; called by muse, mutect2, varscan2
- OR10H1 | c.666C>T p.I222= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs1048040148, COSV58472060; called by muse, mutect2, varscan2
- OR14J1 | c.123C>T p.L41= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV65845746; called by muse, mutect2, varscan2
- OR1L8 | c.501C>T p.L167= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV59186675; called by muse, mutect2, varscan2
- OR2T10 | c.486C>T p.I162= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs199844378; called by muse, mutect2, varscan2
- OR56A3 | c.246C>T p.I82= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV61569385; called by muse, varscan2
- OR8D1 | c.96G>A p.L32= | Silent (SNP) | VAF 26/78 reads (33%) | called by muse, mutect2, varscan2
- OTX2 | c.543G>A p.Q181= (on ENST00000408990 / NM_172337.3; = p.Q189= on NM_021728.4) | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1257366193, COSV59766573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OVOL2 | c.402G>A p.L134= | Silent (SNP) | VAF 46/67 reads (69%) | catalogued as rs1389098670, COSV53860883; called by muse, mutect2, varscan2
- OXA1L | c.1113C>T p.F371= (on ENST00000285848; = p.F311= on NM_005015.5) | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV53537446; called by muse, mutect2, varscan2
- P2RX2 | c.111G>A p.R37= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV57683045; called by muse, mutect2, varscan2
- P2RX7 | c.1782T>C p.P594= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1565983671, COSV55855932; called by muse, mutect2, varscan2
- PCDHA7 | c.1899G>A p.T633= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV65344998; called by muse, mutect2, varscan2
- PCDHB15 | c.1260C>T p.T420= | Silent (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1827C>T p.A609= | Silent (SNP) | VAF 46/179 reads (26%) | catalogued as rs782676792, COSV50757818, COSV50778882; called by muse, mutect2, varscan2
- PLD2 | c.2613C>T p.S871= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV54004681; called by muse, mutect2, varscan2
- PLXNB2 | c.2538C>T p.S846= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV63782527; called by muse, mutect2, varscan2
- POLR3A | c.3786C>T p.A1262= | Silent (SNP) | VAF 263/309 reads (85%) | catalogued as rs184961157, COSV64931283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPARGC1A | c.1098T>G p.G366= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV53529283; called by muse, mutect2, varscan2
- PTPN11 | c.1704C>T p.P568= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as rs749748127, COSV100692884, COSV61010073; called by muse, mutect2, varscan2
- PXDNL | c.2703G>A p.G901= | Silent (SNP) | VAF 131/149 reads (88%) | catalogued as COSV62490515; called by muse, mutect2, varscan2
- PXDNL | c.1452C>T p.G484= | Silent (SNP) | VAF 40/382 reads (10%) | catalogued as COSV62490521; called by muse, mutect2, varscan2
- RBP4 | c.339C>T p.S113= | Silent (SNP) | VAF 84/92 reads (91%) | catalogued as COSV65160385; called by muse, mutect2, varscan2
- ROBO4 | c.1884G>A p.R628= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV60625199; called by muse, mutect2, varscan2
- SALL4 | c.2073C>T p.I691= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs1392193733, COSV53850523; called by muse, mutect2, varscan2
- SERPINB12 | c.372C>T p.F124= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV54033690; called by muse, mutect2, varscan2
- SEZ6 | c.1695G>A p.L565= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV57981620; called by muse, mutect2, varscan2
- SEZ6L | c.2478G>A p.V826= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV50668291, COSV50668348; called by muse, mutect2, varscan2
- SHROOM3 | c.3933C>T p.S1311= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs754362155, COSV56032033; called by muse, mutect2, varscan2
- SLC1A7 | c.780C>T p.I260= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs375544818, COSV65200725; called by muse, mutect2, varscan2
- SLC7A8 | c.465C>T p.F155= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV57554641; called by muse, mutect2, varscan2
- SLC8A1 | c.2322C>T p.F774= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs770499303, COSV60470065, COSV60497665; called by muse, mutect2, varscan2
- SORL1 | c.6210C>T p.I2070= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV52756441; called by muse, mutect2, varscan2
- SPOCK3 | c.1014C>T p.I338= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV62728595; called by muse, mutect2, varscan2
- SYCP1 | c.412A>C p.R138= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs781567716, COSV65698543; called by muse, mutect2, varscan2
- SYT13 | c.681C>T p.L227= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs1328233084, COSV50073098; called by muse, mutect2, varscan2
- TEX29 | c.228C>T p.T76= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV52095690; called by muse, mutect2, varscan2
- TIE1 | c.2745C>T p.I915= | Silent (SNP) | VAF 170/379 reads (45%) | catalogued as rs1414781595, COSV65250138; called by muse, mutect2, varscan2
- TMEM176A | c.183G>A p.Q61= | Silent (SNP) | VAF 97/107 reads (91%) | catalogued as COSV50241944; called by muse, mutect2, varscan2
- TRPC6 | c.228G>A p.G76= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs1175967739, COSV60256512; called by muse, mutect2, varscan2
- UTP14C | c.1728C>T p.P576= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV73000712; called by muse, mutect2, varscan2
- VSIR | c.684G>A p.Q228= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1211670957, COSV56471257; called by muse, mutect2, varscan2
- ZNF101 | c.702C>T p.I234= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs751352534, COSV58909195; called by muse, mutect2, varscan2
- ZNF267 | c.2178C>T p.N726= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1338966988, COSV56253810; called by muse, mutect2, varscan2
- ZNF772 | c.1119T>A p.T373= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV58411027; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7741C>T | Intron (SNP) | VAF 16/20 reads (80%) | catalogued as COSV100876049; called by muse, mutect2, varscan2
- MIR329-2 | n.76C>T | RNA (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.10361-4982C>T | Intron (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100604419; called by muse, mutect2, varscan2
- WNK1 | c.2140-2232C>T | Intron (SNP) | VAF 125/522 reads (24%) | catalogued as COSV60036455; called by muse, mutect2, varscan2
